MMRF case MMRF_2306 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/55e43550-6f25-4a83-9410-b013ea2b710f

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 40 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 40.7 years (14,857 days); ISS stage: II; Days to last known disease status: 778 days (2.1 years); Days to last follow up: 778 days (2.1 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 14 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 98 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 21 days; Days to treatment end: 119 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 105 days; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 245 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 126 days; Days to treatment end: 168 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 266 days; Days to treatment end: 267 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 266 days; Days to treatment end: 364 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 266 days; Days to treatment end: 287 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 273 days; Days to treatment end: 281 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 294 days; Days to treatment end: 365 days (1.0 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 294 days; Days to treatment end: 371 days (1.0 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 425 days (1.2 years); Days to treatment end: 425 days (1.2 years).
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: Second line of therapy; Days to treatment start: 427 days (1.2 years); Days to treatment end: 427 days (1.2 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: Second line of therapy; Days to treatment start: 502 days (1.4 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 516 days (1.4 years); Days to treatment end: 852 days (2.3 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 866 days (2.4 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -22 (ECOG 1): M Protein 3.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 116 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.83 mg/dL; Immunoglobulin G 67.3 g/L; Immunoglobulin A 0.38 g/L; Immunoglobulin M 0.25 g/L; Beta 2 Microglobulin 4 µg/mL; Hemoglobin 5.39 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.33 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.1 mmol/L; Albumin 21 g/L; Total Protein 10.5 g/dL; Glucose 6.05 mmol/L.
- Day 63 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.632 mg/dL; Hemoglobin 6.14 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 128 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 2.86 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 7.1 g/dL; Glucose 10.5 mmol/L.
- Day 147 (ECOG 1): M Protein 0.8 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.31 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.887 mg/dL; Hemoglobin 6.14 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 145 ×10⁹/L; Creatinine 57.5 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.13 mmol/L; Albumin 33 g/L; Total Protein 7 g/dL; Glucose 9.52 mmol/L.
- Day 259 (ECOG 1): M Protein 1.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 31.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.981 mg/dL; Immunoglobulin G 29.4 g/L; Immunoglobulin A 0.623 g/L; Immunoglobulin M 0.381 g/L; Hemoglobin 6.57 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 202 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 9 g/dL; Glucose 6.11 mmol/L.
- Day 343 (ECOG 1): M Protein 0.9 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.651 mg/dL; Immunoglobulin G 17.1 g/L; Immunoglobulin A 0.567 g/L; Immunoglobulin M 0.186 g/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 163 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 7.3 g/dL; Glucose 8.8 mmol/L.
- Day 418 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.928 mg/dL; Immunoglobulin G 18 g/L; Immunoglobulin A 0.462 g/L; Immunoglobulin M 0.166 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 6.3 ×10⁹/L; Absolute Neutrophil 5 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 7.5 g/dL; Glucose 7.48 mmol/L.
- Day 526 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.7 mg/dL; Immunoglobulin G 26.2 g/L; Immunoglobulin A 0.839 g/L; Immunoglobulin M 0.34 g/L; Hemoglobin 6.14 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.18 mmol/L; Albumin 33 g/L; Total Protein 7.6 g/dL; Glucose 8.14 mmol/L.
- Day 610 (ECOG 1): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.44 mg/dL; Immunoglobulin G 16.5 g/L; Immunoglobulin A 1.29 g/L; Immunoglobulin M 0.425 g/L; Hemoglobin 6.26 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 160 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.18 mmol/L; Albumin 36 g/L; Total Protein 6.9 g/dL; Glucose 6.88 mmol/L.
- Day 694 (ECOG 1): M Protein 0.4 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.56 mg/dL; Immunoglobulin G 16.1 g/L; Immunoglobulin A 1.36 g/L; Immunoglobulin M 0.393 g/L; Hemoglobin 6.82 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.4 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.15 mmol/L; Albumin 37 g/L; Total Protein 7.1 g/dL; Glucose 6.99 mmol/L.
- Day 778 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 6.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.14 mg/dL; Immunoglobulin G 16.9 g/L; Immunoglobulin A 1.62 g/L; Immunoglobulin M 0.404 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 151 ×10⁹/L; Creatinine 71.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.08 mmol/L; Albumin 33 g/L; Total Protein 6.9 g/dL; Glucose 7.7 mmol/L.

Other clinical attributes
- Day -22: Weight: 135 kg; Height: 170 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2306_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -22 days.
- Sample MMRF_2306_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -22 days.
